HCMI case HCM-WCMC-0786-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0992e3ff-b15d-4985-988d-8f0a05e717a7

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1942; Vital status: Dead.

Diagnoses (1)
1. Bronchio-alveolar carcinoma, mucinous: ICD-O-3 morphology code: 8253/3; ICD-10 code: C34.32; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 76.8 years (28,050 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 291 days; Days to treatment end: 291 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 291 days; Days to treatment end: 305 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 291 days; Days to treatment end: 291 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 1,294 days (3.5 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 251.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- EGFR: Negative.
- EML4–ALK translocation (Sequencing, NOS): Negative; Second exon: 20.
- KRAS mutation, nos: Positive; Amino-acid change: p.Gly12Asp.
- MET: Negative.
- RET rearrangement: Negative.
- ROS1 rearrangement (FISH): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 131.5 kg; Height: 167.6 cm; BMI: 44.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1976.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-0786-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-0786-C34-01A-S1-HE: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 10; Percent normal cells: 90; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-WCMC-0786-C34-01A-S3-HE: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 50; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-WCMC-0786-C34-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0786-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 9.
